Somatic mutation profile of tumor specimen TCGA-CR-5248-01A (aliquot TCGA-CR-5248-01A-01D-2012-08) from TCGA case TCGA-CR-5248, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G3; Age at diagnosis: 53.2 years (19,441 days).
Specimen TCGA-CR-5248-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b424012-5854-479f-af1e-14031df39146.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-5248-10A (Blood Derived Normal), aliquot TCGA-CR-5248-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12cefa7d-a52d-4c4a-b7f9-0c3efadb468b

The open-access MAF lists 345 somatic variants for this specimen: 257 protein-altering or splice-affecting, 80 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 207, Silent 80, Frame Shift Del 23, Nonsense Mutation 21, Splice Site 4, Intron 2, Frame Shift Ins 2, RNA 2, 5'Flank 1, 3'UTR 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MLH1 | c.381-1G>C p.X127_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as rs267607744, CS1514971; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA4 | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV100933299, COSV64673757; called by muse, mutect2
- ABCB4 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV99711411; called by muse, mutect2, varscan2
- ABCD3 | c.1309G>C p.D437H | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100931484; called by muse, mutect2, varscan2
- ABCF2 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99734943; called by muse, mutect2, varscan2
- ADAM20 | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV99833506, COSV99833612; called by muse, varscan2
- ADAM20 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV99833613; called by muse, varscan2
- AGAP2 | c.1262C>T p.S421L (on ENST00000547588 / NM_001122772.2; = p.S85L on NM_014770.4) | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1331796686, COSV57732831; called by muse, mutect2, varscan2
- AGO3 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV99869495; called by muse, varscan2
- AHNAK2 | c.7753C>T p.Q2585* | Nonsense Mutation (SNP) | VAF 71/300 reads (24%) | catalogued as rs767622670, COSV100319127; called by muse, mutect2, varscan2
- AKAP6 | c.6550G>A p.E2184K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs201039342, COSV55205570; called by muse, mutect2, varscan2
- ANK2 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100004508; called by muse, mutect2, varscan2
- ANKRD53 | c.904-1G>C p.X302_splice (on ENST00000360589 / NM_001115116.2; = p.X344_splice on NM_024933.4) | Splice Site (SNP) | VAF 7/116 reads (6%) | catalogued as COSV99721599; called by muse, mutect2
- ANKS1B | c.1667G>A p.C556Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100248449; called by muse, mutect2, varscan2
- ANKZF1 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as COSV99850945; called by muse, varscan2
- ANKZF1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99850946; called by muse, varscan2
- AOAH | c.431T>A p.V144D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV99332485, COSV99333954; called by muse, mutect2, varscan2
- AP4E1 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99957264; called by muse, mutect2, varscan2
- APOB | c.8203G>C p.D2735H | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99268444; called by muse, mutect2, varscan2
- ARHGEF6 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV51689165, COSV99166766; called by muse, mutect2, varscan2
- ASXL3 | c.2671G>A p.D891N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs1367269737, COSV99326848; called by muse, mutect2, varscan2
- ATF7IP | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99662187; called by muse, mutect2, varscan2
- ATP1B3 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99657599; called by muse, mutect2
- ATP6V1B2 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52354666, COSV99369615; called by muse, mutect2, varscan2
- ATP6V1C2 | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.185); catalogued as COSV99696197; called by muse, mutect2, varscan2
- BCKDHB | c.1076G>C p.R359T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100244160; called by muse, mutect2, varscan2
- BMPR2 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV101001712; called by muse, mutect2, varscan2
- BRF1 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs587640821, COSV100527825; called by muse, mutect2, varscan2
- BRIP1 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99371218; called by muse, mutect2, varscan2
- C12orf4 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.339); catalogued as COSV99712971; called by muse, mutect2, varscan2
- C12orf60 | c.345C>G p.F115L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV99967008; called by muse, mutect2
- C1QTNF3 | c.284G>C p.R95P | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV99180737; called by muse, mutect2, varscan2
- C7orf31 | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV99384210; called by muse, mutect2, varscan2
- CACNG2 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55633093; called by muse, mutect2, varscan2
- CADPS2 | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as rs753192762, COSV57385505; called by muse, varscan2
- CAPN15 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.074); catalogued as COSV54838730; called by muse, varscan2
- CAPN3 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100533537; called by muse, mutect2, varscan2
- CCDC73 | c.2683del p.T895Lfs*8 | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | catalogued as rs764792181; called by mutect2, pindel, varscan2
- CCSER1 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV100396819; called by muse, mutect2, varscan2
- CDCA5 | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV99298068; called by muse, mutect2, varscan2
- CDH3 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 18/109 reads (17%) | catalogued as COSV99869339; called by muse, mutect2, varscan2
- CFAP54 | c.5849G>C p.R1950T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as COSV100733398, COSV61572192; called by muse, mutect2, varscan2
- CHPF | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs777118819, COSV99705359; called by muse, varscan2
- CISH | c.331C>T p.H111Y (on ENST00000348721 / NM_145071.4; = p.H128Y on NM_013324.6) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100811805; called by muse, mutect2, varscan2
- CKB | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV100818972; called by muse, varscan2
- CLOCK | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100012049; called by muse, mutect2, varscan2
- CNOT1 | c.4362G>T p.M1454I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV99801412; called by muse, mutect2, varscan2
- COA7 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as rs141260822, COSV101034480; called by muse, mutect2, varscan2
- COL6A2 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); catalogued as rs759838639, COSV100154403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLGALT2 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); catalogued as COSV100730902, COSV62727504; called by muse, mutect2, varscan2
- CSGALNACT1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs201825362, COSV59975099, COSV59979161; called by muse, mutect2, varscan2
- CYP11A1 | c.48C>A p.C16* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV51432887, COSV99166253; called by muse, mutect2, varscan2
- CYTH2 | c.1056G>T p.M352I (on ENST00000427476; = p.M351I on NM_004228.7) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100287374; called by muse, mutect2, varscan2
- DAGLA | c.2714C>T p.S905L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs780538096, COSV99944775; called by muse, mutect2, varscan2
- DDX11 | c.2288G>C p.R763T (on ENST00000545668 / NM_152438.2; = p.R713T on NM_004399.3) | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.113); catalogued as COSV99300367; called by muse, mutect2, varscan2
- DGKE | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as COSV99401238; called by muse, mutect2, varscan2
- DIS3L2 | c.1678C>G p.L560V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs1170950804, COSV99807409; called by muse, mutect2, varscan2
- DNAH9 | c.3691G>C p.D1231H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99308456; called by muse, mutect2, varscan2
- DNMT3B | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99144785; called by muse, varscan2
- DST | c.12958C>G p.L4320V (on ENST00000361203 / NM_001374722.1; = p.L1908V on NM_015548.5) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); catalogued as rs996209535, COSV55012850; called by muse, mutect2, varscan2
- DYRK1A | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100118354, COSV58292558; called by muse, mutect2, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- EDRF1 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.461); catalogued as COSV100524073, COSV61763667; called by muse, mutect2, varscan2
- EIF2AK1 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52243098, COSV99552412; called by muse, mutect2, varscan2
- EIF2B5 | c.1993G>A p.E665K (on ENST00000647909; = p.E657K on NM_003907.3) | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs776796180, COSV99889535; called by muse, mutect2, varscan2
- ELF1 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as rs1404452405, COSV99523358; called by muse, mutect2, varscan2
- ELF4 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.949); catalogued as rs756574054, COSV100257251; called by muse, mutect2, varscan2
- EPS8L1 | c.935C>T p.S312L (on ENST00000201647 / NM_133180.3; = p.S185L on NM_017729.3) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs751356074, COSV99137227; called by muse, mutect2
- ETS2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV62872572; called by muse, mutect2, varscan2
- EVI5L | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV99563605; called by muse, mutect2, varscan2
- FAM131A | c.440C>T p.A147V (on ENST00000310585; = p.A178V on NM_144635.5) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773412803, COSV99659062; called by muse, mutect2
- FAM53C | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.272); catalogued as rs146380618; called by muse, mutect2, varscan2
- FASLG | c.422del p.K141Rfs*3 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs35774809; called by mutect2, pindel, varscan2
- FBXO10 | c.1512T>G p.I504M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99447345; called by muse, varscan2
- FDXR | c.1045G>C p.E349Q (on ENST00000293195 / NM_024417.5; = p.E355Q on NM_004110.6) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99501536; called by muse, mutect2, varscan2
- FLG | c.9539C>T p.S3180L | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs747040656, COSV100912318; called by muse, mutect2, varscan2
- FLG2 | c.2392G>A p.G798R | Missense Mutation (SNP) | VAF 42/476 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs879140814, COSV101166262; called by muse, mutect2
- FLNC | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV57967314; called by muse, mutect2, varscan2
- FLRT3 | c.1001G>A p.C334Y | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99444651; called by muse, mutect2, varscan2
- FRMD4A | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs755993250, COSV100662598; called by muse, varscan2
- FSIP1 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs148913803, COSV63223760; called by muse, mutect2, varscan2
- G0S2 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753202670, COSV100884483, COSV65433249; called by muse, mutect2, varscan2
- GEM | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as COSV99891673; called by muse, mutect2, varscan2
- GFOD1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 28/120 reads (23%) | catalogued as rs1260015481, COSV101014490, COSV64953289; called by muse, mutect2, varscan2
- GJA9 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV100668177, COSV62532158; called by muse, mutect2, varscan2
- GOLPH3L | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs150623963; called by muse, mutect2, varscan2
- GPR132 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1259630331, COSV100317765; called by muse, mutect2
- GPR55 | c.845G>A p.C282Y | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101235930; called by muse, mutect2, varscan2
- GSDMB | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV100522962; called by muse, mutect2, varscan2
- GTF2F1 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV101081435, COSV66726425; called by muse, mutect2, varscan2
- H1-3 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99768912; called by muse, mutect2, varscan2
- H4C3 | c.203G>C p.R68P | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs778987751, COSV58090178; called by muse, mutect2, varscan2
- HCN2 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); catalogued as rs775274951, COSV99241333; called by mutect2, varscan2
- HGSNAT | c.1701G>A p.W567* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99925536; called by muse, mutect2, varscan2
- HIC2 | c.1323G>C p.L441F | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as COSV101335646; called by muse, mutect2, varscan2
- HIPK4 | c.555G>C p.E185D | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99397111; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as COSV100079911, COSV57134093; called by muse, mutect2, varscan2
- HOXD8 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.17); catalogued as COSV57485742; called by muse, mutect2, varscan2
- HPS3 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | catalogued as COSV99937671; called by muse, mutect2, varscan2
- HSPA6 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV100553981; called by mutect2, varscan2
- HUWE1 | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99474499; called by muse, mutect2, varscan2
- IGSF9 | c.154del p.L52Cfs*79 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | catalogued as rs753928344; called by mutect2, pindel, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- KCNC4 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV100873699; called by muse, mutect2, varscan2
- KCNH7 | c.2462C>G p.S821C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100150102; called by muse, mutect2, varscan2
- KCNT2 | c.1682C>A p.S561* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV54065078, COSV99657109; called by muse, mutect2, varscan2
- KDM3B | c.2769del p.K924Sfs*12 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as COSV58688229; called by mutect2, varscan2
- KIAA2026 | c.3337C>T p.Q1113* | Nonsense Mutation (SNP) | VAF 29/133 reads (22%) | catalogued as COSV101199224; called by muse, mutect2, varscan2
- KIF6 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.978); catalogued as rs761285448, COSV99760997; called by muse, mutect2, varscan2
- KRTAP19-1 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as rs1449180487, COSV66861720; called by muse, mutect2, varscan2
- L2HGDH | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99910600; called by muse, mutect2, varscan2
- LAMA2 | c.4759G>T p.A1587S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV101370889; called by muse, mutect2, varscan2
- LAYN | c.776G>A p.C259Y (on ENST00000375615 / NM_001258390.1; = p.C251Y on NM_178834.5) | Missense Mutation (SNP) | VAF 47/550 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100986284; called by muse, mutect2
- LIMK2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100059109; called by muse, varscan2
- LMBRD1 | c.836A>G p.D279G (on ENST00000649011; = p.D257G on NM_018368.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.756); catalogued as COSV100992725; called by muse, mutect2, varscan2
- LPP | c.679T>G p.S227A | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV100448475; called by muse, mutect2, varscan2
- LRP1B | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV101261690; called by muse, mutect2, varscan2
- LRRC27 | c.927-1G>A p.X309_splice | Splice Site (SNP) | VAF 71/303 reads (23%) | catalogued as COSV100689996, COSV104414775; called by muse, mutect2, varscan2
- LRRC28 | c.1004A>T p.E335V | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100113904; called by muse, mutect2
- LRRC37B | c.986C>G p.P329R | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs1251605591, COSV100496557; called by muse, mutect2, varscan2
- LRRC66 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1177047455, COSV58633395; called by muse, mutect2, varscan2
- MACF1 | c.18803del p.N6268Mfs*32 (on ENST00000372915; = p.N4313Mfs*32 on NM_012090.5) | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs748961150; called by mutect2, varscan2
- MAPK13 | c.1018+1G>A p.X340_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as rs778203783, COSV52983637; called by mutect2, varscan2
- MAPKBP1 | c.1693G>A p.E565K (on ENST00000456763 / NM_001128608.2; = p.E559K on NM_014994.3) | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV52964100; called by muse, mutect2
- MARCHF8 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60572433, COSV60573492; called by muse, mutect2, varscan2
- MCM7 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs752747070, COSV100385205; called by muse, mutect2, varscan2
- METAP2 | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV99705011; called by muse, mutect2, varscan2
- MFSD2A | c.1171G>A p.E391K (on ENST00000372809 / NM_001136493.3; = p.E378K on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100861744; called by muse, mutect2, varscan2
- MIOX | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as rs1345608531, COSV53313420, COSV99327115; called by muse, mutect2
- MOK | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV99513677; called by muse, mutect2, varscan2
- MORC2 | c.1321C>T p.R441* (on ENST00000397641 / NM_001303256.3; = p.R379* on NM_014941.3) | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as rs1401669660, COSV99310540; called by muse, mutect2, varscan2
- MPHOSPH10 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99731328; called by muse, mutect2
- MPHOSPH8 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as rs1254607012, COSV100825235, COSV64056136; called by muse, mutect2, varscan2
- MRPL20 | c.271G>C p.V91L | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100785049; called by muse, mutect2, varscan2
- MTFMT | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99584547; called by muse, mutect2, varscan2
- MTMR6 | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101110862, COSV67808087; called by muse, mutect2, varscan2
- MTUS1 | c.2893C>T p.R965W (on ENST00000262102 / NM_001363061.1; = p.R131W on NM_020749.4) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs924802638, COSV99870709; called by muse, mutect2, varscan2
- MUC17 | c.3880G>A p.E1294K | Missense Mutation (SNP) | VAF 110/571 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100075291, COSV60300727; called by muse, mutect2, varscan2
- MYO5A | c.4627G>C p.V1543L | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100698227; called by muse, mutect2, varscan2
- MYRF | c.111C>G p.I37M (on ENST00000278836 / NM_001127392.3; = p.I28M on NM_013279.4) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765459768, COSV99607968; called by mutect2, varscan2
- NAA25 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as rs1232558434, COSV99928111; called by muse, mutect2, varscan2
- NAV3 | c.5654C>G p.S1885C (on ENST00000397909 / NM_001024383.2; = p.S1863C on NM_014903.6) | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99896235; called by muse, mutect2, varscan2
- NCKAP5L | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs776684576, COSV60131591; called by muse, varscan2
- NECTIN2 | c.1499A>G p.E500G | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV99375309; called by muse, mutect2, varscan2
- NETO1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100199504; called by muse, mutect2, varscan2
- NFATC1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs767042185, COSV53697749; called by muse, mutect2, varscan2
- NFE2L3 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 27/128 reads (21%) | catalogued as rs1292832218, COSV50227701, COSV99284073; called by muse, mutect2, varscan2
- NHSL2 | c.1420G>C p.E474Q (on ENST00000510661; = p.E840Q on NM_001013627.2) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101030376; called by muse, varscan2
- NIBAN2 | c.1629G>C p.Q543H | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV100031996; called by muse, mutect2, varscan2
- NLRP12 | c.2296C>G p.L766V | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV100145865; called by muse, mutect2, varscan2
- NOC3L | c.1235G>C p.R412T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV100993403; called by muse, mutect2, varscan2
- NSUN2 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.552); catalogued as COSV99243482; called by muse, mutect2, varscan2
- OR52K2 | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV57835333, COSV57835966; called by muse, mutect2
- OR5B17 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100641966, COSV62160128; called by muse, mutect2, varscan2
- OR5H6 | c.806G>A p.G269D (on ENST00000642105; = p.G253D on NM_001005479.2) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1417430632, COSV101051823; called by muse, mutect2, varscan2
- OR8G5 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 41/133 reads (31%) | catalogued as COSV100422263, COSV100422627, COSV100422691; called by muse, mutect2, varscan2
- PCDHA6 | c.1925C>G p.S642C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV65342335, COSV65343616; called by muse, mutect2, varscan2
- PCNX1 | c.6785C>G p.S2262C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99457467; called by muse, varscan2
- PCNX1 | c.6823C>T p.R2275W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs370831013; called by muse, varscan2
- PHF7 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100015609; called by muse, mutect2, varscan2
- PIK3R1 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.155); catalogued as COSV99159691; called by muse, mutect2, varscan2
- PLCL1 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101407313; called by muse, mutect2, varscan2
- PLEKHG4B | c.2939A>G p.H980R (on ENST00000283426; = p.H1336R on NM_052909.5) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as COSV99361204; called by muse, mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs772701630; called by mutect2, varscan2
- POLR2F | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 41/214 reads (19%) | catalogued as COSV101347065; called by muse, mutect2, varscan2
- POTEF | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100665401; called by muse, mutect2, varscan2
- PPDPF | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100925650; called by muse, mutect2, varscan2
- PPFIA1 | c.2722G>A p.G908R | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99558091; called by muse, mutect2, varscan2
- PPP1R21 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV54283634; called by muse, mutect2, varscan2
- PPP4R3B | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs746528353, COSV99702790; called by muse, mutect2
- PRM2 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as rs201640369, COSV54112831; called by muse, mutect2, varscan2
- PTPRB | c.2854C>T p.Q952* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99717415, COSV99719233; called by muse, mutect2, varscan2
- RARB | c.812T>G p.L271R (on ENST00000383772 / NM_001290216.2; = p.L264R on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99980413; called by muse, varscan2
- RBL1 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as COSV100727322, COSV60329555; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs762006287; called by mutect2, varscan2
- RELN | c.8984A>G p.Y2995C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100635016; called by muse, mutect2, varscan2
- RIPK4 | c.1015G>A p.D339N (on ENST00000352483; = p.D291N on NM_020639.3) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV60187839; called by muse, mutect2, varscan2
- RNASE9 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100141414; called by muse, mutect2, varscan2
- RNF19A | c.810G>C p.E270D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV100348174; called by muse, mutect2, varscan2
- RP1 | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1244568621, COSV55126440; called by muse, mutect2, varscan2
- RPRD2 | c.1557G>C p.E519D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); catalogued as rs1161539287, COSV100955408; called by muse, mutect2, varscan2
- RRP12 | c.2329C>T p.R777W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.28); catalogued as rs762952867, COSV100213542; called by muse, mutect2, varscan2
- RUSC1 | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as COSV52742041, COSV99430343; called by muse, mutect2, varscan2
- SARM1 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs137938585, COSV99076810; called by muse, varscan2
- SBF2 | c.4840G>A p.E1614K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.029); catalogued as COSV99815959; called by muse, varscan2
- SBF2 | c.4753G>A p.E1585K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.67); catalogued as COSV99815962; called by muse, varscan2
- SCN3A | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1035773270, COSV99328738; called by muse, mutect2, varscan2
- SCPEP1 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as COSV99228025; called by muse, mutect2, varscan2
- SEL1L3 | c.1976G>C p.R659T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV53548358; called by muse, mutect2, varscan2
- SEMA6B | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1327645032, COSV100015205; called by muse, mutect2
- SETD3 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100075524; called by muse, mutect2, varscan2
- SIPA1L1 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100666132; called by muse, mutect2, varscan2
- SLC1A5 | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101314833, COSV69467349; called by muse, mutect2, varscan2
- SLITRK3 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53846333, COSV99580276; called by muse, mutect2, varscan2
- SMARCAD1 | c.495G>C p.L165F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV100759053; called by muse, mutect2
- SOCS5 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100125522; called by muse, mutect2, varscan2
- SPATA31D1 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100783090; called by muse, mutect2, varscan2
- SPEN | c.8689C>G p.P2897A | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV101005659; called by muse, mutect2, varscan2
- SSX2IP | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.898); catalogued as COSV100642767, COSV60551511; called by muse, mutect2
- SYNE3 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs774793672, COSV100516580; called by muse, mutect2, varscan2
- TANGO6 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as COSV99937070; called by muse, mutect2, varscan2
- TDGF1 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99947717; called by muse, mutect2, varscan2
- TDRP | c.188G>C p.R63T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100138669; called by muse, mutect2, varscan2
- TECPR2 | c.2365G>C p.E789Q | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100850239; called by muse, mutect2, varscan2
- TECRL | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV101169442; called by muse, mutect2, varscan2
- TENT5C | c.789C>G p.I263M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.549); catalogued as COSV101033163; called by muse, mutect2, varscan2
- THBS4 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as COSV63471729; called by muse, mutect2, varscan2
- TMC1 | c.2076C>G p.I692M | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1484368059, COSV99920647; called by muse, mutect2, varscan2
- TMEM168 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs779314559, COSV100454816; called by mutect2, varscan2
- TNN | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs776834667, COSV53426449, COSV99513441; called by muse, mutect2, varscan2
- TPK1 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV100766114; called by muse, mutect2, varscan2
- TTC3 | c.2062C>G p.H688D | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100696084, COSV61286083; called by muse, mutect2, varscan2
- TTI2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100659836; called by muse, mutect2, varscan2
- TTN | c.93847G>A p.D31283N (on ENST00000591111; = p.D23859N on NM_003319.4) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | PolyPhen probably damaging (0.998); catalogued as COSV100590005, COSV100632786; called by muse, mutect2, varscan2
- UBE3A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99217948; called by muse, mutect2, varscan2
- UBR4 | c.9472C>G p.Q3158E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as COSV100922011; called by muse, mutect2, varscan2
- UBR4 | c.9311C>G p.S3104* | Nonsense Mutation (SNP) | VAF 40/168 reads (24%) | catalogued as COSV100922013; called by muse, mutect2, varscan2
- VASH1 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV99388221; called by muse, mutect2, varscan2
- VPS53 | c.911G>A p.R304H (on ENST00000571805 / NM_001366253.2; = p.R275H on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV99346043; called by muse, mutect2, varscan2
- WDR17 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99708368; called by muse, mutect2, varscan2
- WDR31 | c.971G>C p.G324A (on ENST00000374193 / NM_001006615.3; = p.G323A on NM_145241.5) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100516636, COSV100516794; called by muse, mutect2, varscan2
- WDSUB1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV100701911; called by muse, mutect2, varscan2
- WIPI2 | c.92C>G p.S31* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | catalogued as COSV99993633; called by muse, mutect2
- YIPF3 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV100397162; called by muse, mutect2, varscan2
- ZBTB12 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs796344107, COSV100977053; called by muse, mutect2, varscan2
- ZBTB2 | c.1208A>G p.N403S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.33); catalogued as COSV100287868; called by muse, mutect2, varscan2
- ZC3H18 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV99964496; called by muse, mutect2, varscan2
- ZFP69B | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.253); catalogued as COSV100848313; called by muse, mutect2, varscan2
- ZNF174 | c.336G>C p.M112I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99237764; called by muse, mutect2, varscan2
- ZNF175 | c.504C>A p.N168K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99219825; called by muse, mutect2, varscan2
- ZNF396 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.187); catalogued as rs1304416750, COSV60475230; called by muse, mutect2, varscan2
- ZNF451 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100675144; called by muse, mutect2, varscan2
- ZNF473 | c.2139G>C p.Q713H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99569174; called by muse, mutect2, varscan2
- ZNF521 | c.2645C>G p.S882C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100833529; called by muse, mutect2, varscan2
- ZNF540 | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100329930; called by muse, mutect2, varscan2
- ZNF543 | c.1370G>C p.G457A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100386957; called by muse, mutect2, varscan2
- ZNF804B | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100306522; called by muse, mutect2, varscan2
- ZSWIM5 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs370878178, COSV100655861; called by muse, mutect2, varscan2
- ABR | c.205del p.D69Mfs*23 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.831dup p.T278Hfs*71 | Frame Shift Ins (INS) | VAF 41/195 reads (21%) | called by mutect2, pindel, varscan2
- BCAR1 | c.1244del p.P415Qfs*56 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- C16orf86 | c.637del p.E213Rfs*44 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- CYP7B1 | c.1097C>G p.S366* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2
- FCGR1A | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); called by muse, varscan2
- FOLR1 | c.61del p.E21Rfs*18 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | called by mutect2, varscan2
- FRYL | c.687del p.R230Efs*2 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- GPR179 | c.3289del p.R1097Vfs*37 (on ENST00000621958; = p.R1096Vfs*37 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- ITPR2 | c.4637del p.N1546Ifs*19 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- LCOR | c.1096del p.M366* | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- LEPROTL1 | c.124del p.Y42Tfs*10 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- MVK | c.417del p.A141Rfs*18 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, varscan2
- NDC80 | c.434_435del p.T145Kfs*3 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | called by pindel, varscan2
- PCDHB9 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCGF3 | c.193del p.L65Cfs*26 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- POLQ | c.5889_5895del p.I1964Tfs*31 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- PTPN2 | c.735dup p.Q246Tfs*39 | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- SPRED3 | c.544del p.Q182Sfs*66 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- ABCC6 | c.3537G>A p.G1179= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs1247512401, COSV99229727; called by muse, mutect2, varscan2
- AGO4 | c.588G>T p.V196= | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as COSV100943111; called by muse, mutect2, varscan2
- AGTPBP1 | c.1968G>A p.P656= (on ENST00000357081 / NM_001330701.2; = p.P616= on NM_015239.2) | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs1415465798, COSV100429976; called by muse, mutect2, varscan2
- AKAP6 | c.2772T>G p.A924= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99804871; called by muse, mutect2, varscan2
- AP1M1 | c.147C>T p.I49= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99358701; called by muse, mutect2, varscan2
- ATP1A3 | c.1597C>T p.L533= (on ENST00000545399 / NM_001256214.2; = p.L520= on NM_152296.5) | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV100132575; called by muse, mutect2, varscan2
- B3GNT7 | c.219C>T p.P73= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99806042; called by muse, mutect2, varscan2
- BSG | c.486C>T p.S162= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs746332382, COSV100345057; called by muse, mutect2, varscan2
- CACNG6 | c.54G>A p.A18= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99403701; called by muse, mutect2
- CFAP47 | c.1275C>T p.F425= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV52884901; called by muse, mutect2, varscan2
- CHFR | c.1785G>A p.T595= (on ENST00000432561 / NM_001161345.1; = p.T554= on NM_018223.2) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1222086097, COSV99905532, COSV99905793; called by mutect2, varscan2
- CLIC4 | c.360C>T p.D120= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as COSV100978223; called by muse, mutect2, varscan2
- CLK2 | c.534A>G p.V178= (on ENST00000368361 / NM_001294339.2; = p.V177= on NM_003993.4) | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV62877216; called by muse, mutect2, varscan2
- CNGA4 | c.1245G>A p.E415= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV101171889; called by muse, mutect2, varscan2
- CPT1C | c.837C>T p.L279= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV99773710; called by muse, mutect2, varscan2
- CRTAM | c.126G>A p.L42= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV99912331; called by muse, mutect2, varscan2
- DNAH5 | c.3648C>T p.V1216= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs1175994969, COSV99454849; called by muse, mutect2, varscan2
- DOCK8 | c.1689C>G p.L563= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs374343164; called by muse, mutect2, varscan2
- EP400 | c.8931G>A p.A2977= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as rs373215107; called by muse, mutect2, varscan2
- EPHA4 | c.309C>T p.F103= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV56046341; called by muse, mutect2, varscan2
- EPX | c.1137G>A p.T379= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs753243977, COSV56595620; called by muse, mutect2, varscan2
- ERAP1 | c.906C>T p.P302= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99701327; called by muse, mutect2
- ERN2 | c.1989C>T p.L663= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV55621374; called by muse, mutect2, varscan2
- ESYT1 | c.195G>C p.L65= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99920361; called by muse, mutect2
- FANCI | c.153C>T p.F51= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV100168657; called by muse, mutect2, varscan2
- FKBP2 | c.105C>G p.V35= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as COSV100501868; called by muse, mutect2
- GAS2L1 | c.747G>C p.L249= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53331373, COSV99329743; called by muse, mutect2, varscan2
- GCC1 | c.2076C>T p.G692= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs753671181, COSV100365693; called by muse, mutect2, varscan2
- GCNT3 | c.1143C>G p.P381= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as COSV68532723; called by muse, mutect2, varscan2
- GTF3C1 | c.4893G>C p.R1631= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100649773; called by muse, mutect2, varscan2
- HECTD4 | c.12366C>T p.F4122= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV101108404; called by muse, mutect2, varscan2
- HTR6 | c.381C>G p.L127= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV99230513; called by muse, mutect2
- IGSF10 | c.7497T>C p.Y2499= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV99196921; called by muse, mutect2
- ITGB2 | c.759C>T p.R253= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs768662500, COSV100186168; called by muse, mutect2, varscan2
- KCND3 | c.978C>T p.F326= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100138537; called by muse, mutect2, varscan2
- KIAA0319L | c.1998C>A p.T666= | Silent (SNP) | VAF 46/176 reads (26%) | catalogued as COSV100357764; called by muse, mutect2, varscan2
- LMBRD1 | c.1038C>T p.F346= (on ENST00000649011; = p.F324= on NM_018368.4) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs1263478569, COSV100992724; called by muse, mutect2, varscan2
- LRSAM1 | c.1917G>A p.L639= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs1564286565, COSV100031995; called by muse, mutect2, varscan2
- MAP3K11 | c.528C>A p.I176= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100482775; called by mutect2, varscan2
- MAP3K5 | c.747C>T p.I249= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100753343; called by muse, mutect2, varscan2
- MCM9 | c.249C>T p.S83= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100285071; called by muse, mutect2, varscan2
- MLC1 | c.1086C>T p.F362= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs751390945, COSV100286591; ClinVar: benign; called by muse, mutect2, varscan2
- MON1A | c.975G>A p.S325= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs369861421; called by muse, mutect2, varscan2
- MTMR6 | c.381C>G p.L127= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV101110861; called by muse, mutect2, varscan2
- NDST2 | c.774T>C p.R258= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100014399; called by muse, mutect2, varscan2
- OR11H1 | c.405C>G p.L135= | Silent (SNP) | VAF 9/50 reads (18%) | called by mutect2, varscan2
- OR4C46 | c.535C>T p.L179= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as rs554045341, COSV100061044; called by muse, mutect2, varscan2
- OR6C76 | c.396C>A p.I132= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as COSV100094367; called by muse, mutect2, varscan2
- OR7G3 | c.582C>T p.I194= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV100555765; called by muse, mutect2, varscan2
- P4HA2 | c.1449T>G p.A483= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99387484; called by muse, mutect2, varscan2
- PNCK | c.573G>A p.K191= (on ENST00000340888 / NM_001366975.1; = p.K274= on NM_001039582.3) | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100562546; called by muse, mutect2
- POGK | c.1542G>C p.L514= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100902618; called by muse, mutect2, varscan2
- PPP1R13B | c.1239G>A p.P413= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs12891833, COSV99162975; called by muse, mutect2, varscan2
- PRSS58 | c.669C>A p.I223= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101616171; called by muse, mutect2, varscan2
- PTCD2 | c.1143C>G p.L381= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100349144; called by muse, mutect2
- PYGL | c.87G>A p.K29= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV99369157; called by muse, mutect2, varscan2
- RASD1 | c.147C>T p.F49= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99245930; called by muse, mutect2, varscan2
- RPS6KB2 | c.474G>A p.T158= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs755297940, COSV100412399; called by muse, mutect2, varscan2
- SERPIND1 | c.615G>A p.L205= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV99300507; called by muse, mutect2, varscan2
- SETBP1 | c.2688C>T p.F896= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99955214; called by muse, mutect2, varscan2
- SLC2A10 | c.747C>T p.N249= | Silent (SNP) | VAF 39/163 reads (24%) | catalogued as rs41283042, COSV63713724; called by muse, mutect2, varscan2
- SLC2A3 | c.1359C>T p.T453= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV99307010; called by muse, mutect2, varscan2
- SLFN12 | c.1593G>A p.L531= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100513245; called by muse, mutect2, varscan2
- SLIT2 | c.1476T>C p.Y492= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV99887727; called by muse, mutect2, varscan2
- STKLD1 | c.762C>A p.A254= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV100912233; called by muse, mutect2, varscan2
- STRA8 | c.30C>G p.L10= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV99312685; called by muse, mutect2, varscan2
- TFAP2B | c.789C>T p.L263= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99540953; called by muse, mutect2, varscan2
- TREM2 | c.507C>T p.P169= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs769493472, COSV100632718; called by muse, mutect2, varscan2
- TRIO | c.1026G>A p.L342= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100711067, COSV60092103; called by muse, mutect2, varscan2
- TSPOAP1 | c.564G>A p.L188= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV99273038; called by muse, mutect2, varscan2
- VEPH1 | c.576G>A p.Q192= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100748096; called by muse, mutect2, varscan2
- ZACN | c.705C>T p.I235= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as rs143332874; called by muse, mutect2, varscan2
- ZMIZ1 | c.2232C>T p.I744= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV57895555; called by muse, varscan2
- ZNF253 | c.657G>A p.K219= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs769196617, COSV100849610; called by muse, mutect2, varscan2
- ZNF284 | c.483C>A p.I161= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV101399115; called by muse, mutect2, varscan2
- ZNF512B | c.576C>T p.I192= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs143583869, COSV53872617; called by muse, mutect2, varscan2
- ZNF536 | c.198G>A p.E66= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100836056; called by muse, mutect2, varscan2
- ZNF629 | c.918C>T p.L306= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV99355062; called by muse, mutect2, varscan2
- ZNF839 | c.1548G>A p.E516= (on ENST00000558850 / NM_001267827.1; = p.E632= on NM_018335.5) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1307388273, COSV99216466; called by muse, mutect2, varscan2
- ZNHIT2 | c.735C>G p.L245= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs368051543, COSV99659430; called by muse, mutect2, varscan2
- ARFGAP1 | c.718-991G>A | Intron (SNP) | VAF 34/177 reads (19%) | catalogued as COSV100796740; called by muse, mutect2, varscan2
- CCDC144B | n.535A>G | RNA (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- COL18A1-AS1 | n.1578G>A | RNA (SNP) | VAF 25/78 reads (32%) | catalogued as rs138010199; called by muse, mutect2, varscan2
- LEKR1 | c.*1489G>T | 3'UTR (SNP) | VAF 22/141 reads (16%) | catalogued as COSV100739366; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791806 C>T | 3'Flank (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- RPAIN | c.-1G>A | 5'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as rs1017495711, COSV99852024; called by muse, mutect2
- TTN | c.10360+5483C>G | Intron (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100632789; called by mutect2, varscan2
- UTS2 | chr1:7853413 G>T | 5'Flank (SNP) | VAF 8/56 reads (14%) | catalogued as COSV99276977; called by muse, mutect2, varscan2
